Somatic mutation profile of tumor specimen TCGA-18-3412-01A (aliquot TCGA-18-3412-01A-01D-0983-08) from TCGA case TCGA-18-3412, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.1 years (19,025 days).
Specimen TCGA-18-3412-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38780d5a-69c8-49be-b472-13468a46b90a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3412-11A (Solid Tissue Normal), aliquot TCGA-18-3412-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dda4c3c-10f7-4423-92cc-47fb46b427da

The open-access MAF lists 106 somatic variants for this specimen: 82 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 71, Silent 24, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Translation Start Site 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM7 | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51542094, COSV99443138; called by mutect2, varscan2
- ADAMTS18 | c.514C>G p.R172G | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51418075; called by muse, mutect2, varscan2
- AHNAK | c.10322A>C p.E3441A | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57218276; called by muse, mutect2, varscan2
- AKAP6 | c.4385A>C p.H1462P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55219568; called by muse, mutect2
- ANK2 | c.2932G>A p.G978S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52170263; called by muse, mutect2, varscan2
- ANO5 | c.159G>T p.L53F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs754495816, COSV61086986; called by muse, mutect2, varscan2
- AOC1 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV62869528; called by muse, mutect2, varscan2
- APBA2 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67105119; called by muse, mutect2, varscan2
- APC | c.4177C>A p.L1393I | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57355852; called by muse, mutect2, varscan2
- ARHGEF11 | c.3052A>T p.S1018C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); catalogued as COSV59355645; called by muse, mutect2, varscan2
- ASB5 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.111); catalogued as COSV56672130; called by muse, varscan2
- CABIN1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs559933959, COSV54084479; called by muse, mutect2, varscan2
- CAP1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV61223788; called by muse, mutect2, varscan2
- CCDC170 | c.1701T>G p.N567K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV53342550; called by muse, varscan2
- CCDC8 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.681); catalogued as rs1159077906, COSV56773861; called by muse, mutect2, varscan2
- CD109 | c.3623C>T p.T1208I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV54652120; called by muse, mutect2, varscan2
- CD163L1 | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58016126, COSV58022652; called by muse, mutect2, varscan2
- CHN1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV55034355; called by muse, mutect2, varscan2
- CREBBP | c.7152C>A p.H2384Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV52129286; called by muse, mutect2, varscan2
- CSRNP3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58780761; called by muse, mutect2, varscan2
- DCAF15 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV54330953; called by muse, mutect2
- DYNC1H1 | c.5970C>A p.Y1990* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV64138583; called by muse, mutect2, varscan2
- ELF1 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53500029; called by muse, varscan2
- ELL | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs913186416, COSV53213697; called by muse, mutect2, varscan2
- ELOA | c.2330T>C p.V777A | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.545); catalogued as COSV69310644; called by muse, mutect2, varscan2
- EPHB1 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.28); catalogued as rs373296912, COSV67661955; called by muse, mutect2, varscan2
- FLI1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.159); catalogued as COSV61381715; called by muse, mutect2, varscan2
- FN1 | c.4791G>A p.M1597I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.159); catalogued as COSV60556578; called by muse, mutect2, varscan2
- FRYL | c.3509T>C p.M1170T | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs995701886, COSV51951736; called by muse, mutect2, varscan2
- GABRA6 | c.641C>G p.T214R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.969); catalogued as COSV50878062, COSV50884550; called by muse, mutect2, varscan2
- GCAT | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs369199038; called by muse, mutect2, varscan2
- GLRA3 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- GLT1D1 | c.872A>T p.N291I (on ENST00000442111 / NM_001366889.1; = p.N211I on NM_144669.3) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV55883786; called by muse, mutect2, varscan2
- GPBP1L1 | c.886-2A>T p.X296_splice | Splice Site (SNP) | VAF 17/20 reads (85%) | catalogued as COSV51970639; called by muse, mutect2, varscan2
- HCN1 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs775543627, COSV57495256; called by muse, mutect2, varscan2
- LRATD1 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54473297; called by muse, mutect2, varscan2
- MED1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV56126246; called by muse, mutect2, varscan2
- MINAR1 | c.2078G>A p.S693N | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs745998897, COSV59584172; called by muse, mutect2, varscan2
- MNS1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV53069138; called by muse, mutect2, varscan2
- MSLN | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.722); catalogued as COSV67020199; called by muse, mutect2, varscan2
- NBEAL1 | c.5857C>T p.L1953F | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs267599164, COSV68916340; called by muse, mutect2, varscan2
- NEK5 | c.184A>G p.N62D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62880709; called by muse, mutect2, varscan2
- NF1 | c.7895A>T p.D2632V (on ENST00000358273 / NM_001042492.3; = p.D2611V on NM_000267.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CS1311553, COSV62200174, COSV62208629; called by muse, mutect2, varscan2
- NLRP8 | c.2012A>T p.K671M | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV52589797; called by muse, mutect2, varscan2
- NUP205 | c.4447C>T p.R1483* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV53654552; called by muse, mutect2, varscan2
- OR10J5 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV58386616; called by muse, mutect2, varscan2
- OR2T8 | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV60663288; called by muse, mutect2, varscan2
- OR4C16 | c.197T>A p.L66* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as COSV58941797, COSV58942744; called by muse, mutect2, varscan2
- OR4P4 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58920552, COSV58922640; called by muse, mutect2, varscan2
- OR6K3 | c.263G>T p.W88L (on ENST00000368146; = p.W72L on NM_001005327.2) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63745576, COSV63745883; called by muse, mutect2, varscan2
- PDIA4 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV53725404; called by muse, varscan2
- PLEKHG3 | c.1579A>T p.M527L (on ENST00000394691; = p.M583L on NM_001308147.2) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV55981143; called by muse, mutect2, varscan2
- POSTN | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV65713503; called by muse, varscan2
- PRKAA2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs771285921, COSV64803170; called by muse, mutect2, varscan2
- PRLR | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV51497256; called by muse, mutect2, varscan2
- PSKH2 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV52611161, COSV99404914; called by muse, mutect2, varscan2
- RAPGEF2 | c.3642A>T p.L1214F | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.197); catalogued as rs1167418001, COSV52430017; called by muse, mutect2, varscan2
- RASSF5 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV62425926, COSV62426319; called by muse, mutect2, varscan2
- RBM27 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as rs780516904, COSV54591429; called by muse, varscan2
- RGS9 | c.1612C>A p.Q538K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV52226725; called by muse, mutect2, varscan2
- SI | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV52285951; called by muse, mutect2, varscan2
- SLC28A1 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs757554044, COSV54481275; called by mutect2, varscan2
- SMARCA2 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61809292; called by muse, mutect2, varscan2
- SMARCC2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV57220841; called by muse, mutect2, varscan2
- SNAI1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1259181798, COSV54864385; called by muse, mutect2, varscan2
- SPATA31D1 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV61197757; called by muse, mutect2, varscan2
- SPIRE1 | c.2269T>C p.*757Rext*20 (on ENST00000409402 / NM_001128626.2; = p.*743Rext*20 on NM_020148.3) | Nonstop Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV59158459; called by muse, mutect2, varscan2
- STIM1 | c.1313G>C p.G438A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1403228947, COSV56156914; called by muse, mutect2, varscan2
- SYT9 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as COSV100607544, COSV59620833; called by muse, mutect2, varscan2
- TBC1D9B | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV100783689, COSV62282488; called by muse, mutect2, varscan2
- TMEM45B | c.275T>C p.M92T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55654355; called by muse, mutect2, varscan2
- TNRC6B | c.461C>G p.S154* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV57299954; called by muse, mutect2, varscan2
- TRIM68 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs377284065; called by muse, mutect2, varscan2
- TRPV5 | c.2164del p.D722Mfs*10 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as COSV54686165; called by mutect2, pindel, varscan2
- UNC13A | c.1688C>T p.T563M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1239657095, COSV53192997; called by mutect2, varscan2
- VAV2 | c.937-2A>T p.X313_splice (on ENST00000371850 / NM_001134398.2; = p.X308_splice on NM_003371.4) | Splice Site (SNP) | VAF 9/12 reads (75%) | catalogued as COSV64082911; called by muse, mutect2, varscan2
- ZNF786 | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV60276858; called by muse, mutect2, varscan2
- ZSWIM2 | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV54576678; called by muse, mutect2, varscan2
- COL4A4 | c.2652dup p.G885Rfs*12 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- KIAA1217 | c.1218_1224del p.A407Pfs*73 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- POTEA | c.958G>C p.E320Q (on ENST00000519951 / NM_001005365.2; = p.E274Q on NM_001002920.1) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RBMXL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); called by mutect2, varscan2
- ASB15 | c.150C>A p.A50= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV51927027; called by muse, mutect2, varscan2
- CBL | c.333A>G p.E111= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV50644014; called by muse, mutect2, varscan2
- COL6A6 | c.366C>A p.P122= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV62029118, COSV62029248; called by muse, mutect2, varscan2
- DSC3 | c.1260A>T p.V420= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV64573731; called by muse, mutect2, varscan2
- EIF2A | c.1650G>A p.L550= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as COSV56407518; called by muse, mutect2, varscan2
- GABRB3 | c.789G>T p.V263= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54671064; called by muse, mutect2, varscan2
- HMCN1 | c.13782T>C p.L4594= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV54913212; called by muse, varscan2
- IGHM | c.630G>A p.A210= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs190574154; called by muse, mutect2, varscan2
- IL1R2 | c.492C>T p.D164= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs201321487, COSV60207389; called by mutect2, varscan2
- KCNA10 | c.576G>A p.L192= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV63904882; called by muse, mutect2, varscan2
- MAGEF1 | c.226C>T p.L76= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as COSV58634058; called by muse, mutect2, varscan2
- MAP4K1 | c.1623G>C p.R541= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as COSV67711146; called by muse, varscan2
- MAP4K1 | c.1581G>C p.R527= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV67711156; called by muse, mutect2
- PPARGC1B | c.2130G>A p.R710= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV58530730; called by muse, mutect2, varscan2
- PROSER1 | c.1650C>T p.S550= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV61488329; called by muse, mutect2, varscan2
- PRSS45P | c.150G>A p.K50= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1291574226, COSV70577364; called by muse, mutect2, varscan2
- SAXO2 | c.1191C>G p.A397= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV59754399; called by muse, mutect2, varscan2
- SEC14L5 | c.1245C>T p.T415= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs753178893, COSV52039538; called by muse, varscan2
- SLC2A14 | c.129C>A p.I43= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV61587173; called by muse, varscan2
- SLC6A14 | c.870A>C p.S290= | Silent (SNP) | VAF 21/254 reads (8%) | catalogued as COSV64147634; called by muse, mutect2
- SLITRK6 | c.1194T>C p.R398= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV68390604; called by muse, mutect2, varscan2
- SPTLC3 | c.882A>G p.R294= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV65466638; called by muse, mutect2, varscan2
- TAS2R16 | c.159C>T p.G53= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV50797593; called by muse, mutect2, varscan2
- VPS8 | c.3084C>A p.I1028= (on ENST00000625842 / NM_001349294.1; = p.I1026= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54989423; called by muse, mutect2, varscan2
